Somatic mutation profile of tumor specimen TCGA-VF-A8AD-01A (aliquot TCGA-VF-A8AD-01A-11D-A435-10) from TCGA case TCGA-VF-A8AD, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 37.0 years (13,499 days).
Specimen TCGA-VF-A8AD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2728b8d9-cfb5-49f0-8061-135f36a9a023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VF-A8AD-10A (Blood Derived Normal), aliquot TCGA-VF-A8AD-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10dc540a-774a-4444-89cf-8ea7bf663fa1

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, Nonsense Mutation 3, 3'Flank 1, 5'UTR 1, Frame Shift Del 1, Splice Region 1, Splice Site 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICD2 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1263986082; called by muse, mutect2, varscan2
- CPZ | c.1831G>C p.G611R (on ENST00000360986 / NM_001014447.3; = p.G600R on NM_003652.3) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs748345296; called by muse, mutect2, varscan2
- IGHV3-53 | c.46+1G>T p.X16_splice | Splice Site (SNP) | VAF 26/125 reads (21%) | catalogued as rs1400185098; called by muse, mutect2, varscan2
- KRTAP13-1 | c.517T>C p.*173Rext*4 | Nonstop Mutation (SNP) | VAF 45/162 reads (28%) | catalogued as rs141793094, COSV62664242; called by muse, mutect2, varscan2
- SEC63 | c.1577C>G p.S526* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as CM063124; called by muse, mutect2, varscan2
- C2orf69 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- DDX47 | c.1106+4A>C | Splice Region (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- FAT4 | c.3397G>T p.G1133* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- FER1L5 | c.4199A>T p.K1400M (on ENST00000623019; = p.K1373M on NM_001293083.2) | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- FOXM1 | c.1452_1492del p.L484Ffs*24 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | called by mutect2, pindel*
- IRF6 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- SPEF2 | c.3428C>T p.T1143I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC146 | c.939G>A p.K313= | Silent (SNP) | VAF 42/275 reads (15%) | catalogued as rs909346926; called by muse, mutect2, varscan2
- CYP4Z1 | c.54C>A p.I18= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV61966150; called by muse, mutect2, varscan2
- JAK3 | c.2001C>T p.I667= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- KCNK3 | c.582C>T p.F194= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as COSV57193463; called by muse, mutect2, varscan2
- OR52N4 | c.693C>T p.S231= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as COSV57891465; called by muse, mutect2, varscan2
- C4A | chr6:32005949 G>T | 3'Flank (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- DLD | c.-48G>T | 5'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs555589405, COSV52737905; called by muse, mutect2, varscan2
- SDCBP2 | c.225+52T>C | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
